Surgical pathology report (de-identified scan), TCGA case TCGA-P3-A6T7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Fred Hutchinson, specimen TCGA-P3-A6T7-01A (Primary Tumor).

[page 1 of 3]
ICD-3
Carcinoma, squamous cell NOS
807013
Site Floor mouth NOS
C04.9

CASE:

RECEIVED:

HW 8/9/13

CLINICAL DATA:

Composite resection SCC.

GROSS DESCRIPTION:

A) Received in a container of formalin labeled "level IIB" are two tan-yellow congested fragments of lobulated tissue measuring 4.5 x 3.0 x 1 cm in aggregate dimension. There are fatty cut surfaces admixed with a few lymph node candidates ranging from 0.3 to 1 cm. Also identified on cut surfaces is a 1.0 x 0.5 x 0.5 cm fragment of apparent salivary gland. It has unremarkable cut surfaces. Representative sections are submitted labeled: A1 - possible salivary gland; A2 - six individual lymph node candidates; A3 - three individual lymph node candidates.

B) Received fresh in a container designated "right neck dissection single 4 double 1" is an 18 x 5 x 1.5 cm portion of yellow, lobulated, fibrofatty tissue. The specimen is separated into approximate level I through IV and searched for lymph nodes. In level I there is a 4 x 3 x 2 cm apparent salivary gland. In level III there is a 2.5 x 2.5 x 2 cm grossly positive lymph node from which a sample was taken for the

Representative sections are submitted labeled: B1 - salivary gland; B2 - three candidate lymph nodes, level I; B3 - five candidate lymph nodes, level I; B4 - four candidate lymph nodes, level I; B5 - three candidate lymph nodes, level I; B6 - one candidate lymph node, bisected, level II; B7 - four candidate lymph nodes, level II; B8 - two candidate lymph nodes, level II; B9 - five candidate lymph nodes, level III; B10 - four candidate lymph nodes, level III; B11 - one candidate lymph node, bisected, level III; B12 - one candidate lymph node, bisected, level III; B13 - grossly positive node representative section, level III; B14 - four candidate lymph nodes, level IV; B15 - five candidate lymph nodes, level IV; B16 - five candidate lymph nodes, level IV; B17 - two candidate lymph nodes, level IV.

C) Received fresh in a container labeled "composite resection" is a 92 gm, 6.5 x 5.5 x 5.0 cm portion of soft tissue, mandible and eight attached teeth. The margins of resection are inked as follows: orange posterior bone and soft tissue, black deep, blue anterior soft tissue and bone. There is an obvious 5.0 x 3.0 cm tan-yellow lobulated mass on the underside of the tongue, extending to the anterior portion where the gums meet the teeth. The soft tissues are serially-sectioned to reveal a 4.3 x 3.0 x 2.0 cm tan-white firm mass that appears to abut the orange and black margins but is grossly free of the blue anterior margin. The mandible is serially-sectioned to reveal tan-yellow firm cut surfaces. The tumor focally abuts the periosteum but does not appear to grossly invade the bone. Sections of bone are submitted for decalcification. Cassette list: C1-C3 - posterior/right margin, C4 - mass with closest relationship to orange (posterior/right margin), C5 - mass with closest relationship to black (deep) margin, C6 - blue anterior margin, C7 - black deep margin; C8 - posterior right orange bony margin; C9 - anterior left blue bony margin; C10, C11 - portions of possible bony involvement.

D) Received fresh in a container for frozen labeled "anterior margin" is a 0.6 x 0.3 x 0.3 cm tan, irregular soft tissue. The specimen is marked with

[page 2 of 3]
blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

E) Received fresh in a container for frozen labeled "left middle margin" is a 0.6 x 0.3 x 0.3 cm tan, irregular soft tissue which is marked with black ink and entirely submitted for frozen. The frozen section residue is submitted in block

F) Received fresh in a container for frozen labeled "left posterior margin" is a 0.7 x 0.2 x 0.2 cm tan, irregular soft tissue. The specimen is marked with blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

G) Received fresh in a container for frozen labeled "right middle margin" is a 0.6 x 0.3 x 0.2 cm tan, irregular soft tissue which is marked with blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

H) Received fresh in a container for frozen labeled "right posterior margin" is a 0.4 x 0.3 x 0.2 cm tan, irregular soft tissue which is marked with black ink and entirely submitted for frozen. The frozen section residue is submitted in block

I) Received fresh in a container for frozen labeled "anterior deep margin" is a 0.8 x 0.3 x 0.2 cm tan, irregular soft tissue which is marked with black ink and entirely submitted for frozen. The frozen section residue is submitted in block

J) Received fresh in a container for frozen labeled "posterior deep margin" are two tan, rubbery fragments of tissue measuring 0.7 x 0.5 x 0.3 cm and 0.6 and 0.4 x 0.2 cm. These fragments are marked with blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

K) Received fresh in a container for frozen labeled "left bone marrow" is a 0.3 x 0.2 x 0.2 cm tan-red fragment of tissue which is marked with black ink and entirely submitted for frozen. The frozen section residue is submitted in block

INTRAOPERATIVE CONSULTATION:

D-JFS: No carcinoma identified.

KFS: No tissue on sections/difficult frozen section, defer to permanents.

FINAL DIAGNOSIS:

A) Lymph nodes, level 2 B, excision: Salivary gland and 8 lymph nodes with no evidence of carcinoma (0/8).

B) Right neck dissection:

1. 2 of 39 lymph nodes with metastatic squamous cell carcinoma, extracapsular extension identified (2/39).
2. Salivary gland with no evidence of carcinoma.

C) Mandible, anterior composite resection: Squamous cell carcinoma with the

[page 3 of 3]
following features:

1. Moderately differentiated.
2. Size: 4.3 cm
3. No bony involvement identified.
4. Margins: Extending with within 0.1 cm of the posterior, 0.2 cm of the deep, and > 0.5 cm from the anterior specimen margin.
5. Lymphovascular invasion identified.
6. Perineural invasion identified.
7. Minimal pathologic stage is pT3N2b

D-K) Additional margins, as designated above, biopsies: Fibrofatty tissue, skeletal muscle, and bone with no evidence of carcinoma.

Procedures used to establish the diagnosis:
Routine

Source: NCI Genomic Data Commons file dcc2235c-189e-4340-8779-1b4a0d1ce4f1 (TCGA-P3-A6T7.4B4A1FFA-7BF2-47D5-8160-BE3A328F103F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).